Somatic mutation profile of tumor specimen MMRF_1137_4_BM_CD138pos (aliquot MMRF_1137_4_BM_CD138pos_T1_KBS5U_L07203) from MMRF case MMRF_1137, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.8 years (24,046 days).
Specimen MMRF_1137_4_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 995b3608-6182-4694-ab40-0ebf29972a60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1137_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1137_1_PB_Whole_C1_KHS5U_L13429; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dfff6a5-80cb-4f15-8305-45298f853899

The open-access MAF lists 149 somatic variants for this specimen: 59 protein-altering or splice-affecting, 18 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 37, Silent 18, Intron 16, RNA 10, Splice Site 6, 5'UTR 5, 5'Flank 3, Frame Shift Del 3, Splice Region 2, Nonsense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 63/128 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 47/94 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 156/354 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 87/233 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACE | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770628079, COSV52010307; called by muse, mutect2, varscan2
- ANKRD53 | c.896A>C p.E299A | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV55537989; called by muse, mutect2, varscan2
- ARHGAP11A | c.2021T>C p.F674S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.055); catalogued as rs752293185; called by muse, mutect2, varscan2
- ASTN1 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs148425095; called by muse, mutect2, varscan2
- B3GAT1 | c.80G>C p.S27T | Missense Mutation (SNP) | VAF 88/91 reads (97%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.039); catalogued as COSV56998981; called by muse, mutect2, varscan2
- CCDC30 | c.1046C>T p.S349L (on ENST00000340612; = p.S306L on NM_001080850.3) | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773805083; called by muse, mutect2, varscan2
- CDKN1C | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs1287328131; called by muse, mutect2
- CLNK | c.169G>A p.V57I | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57020198; called by muse, mutect2, varscan2
- FAM170A | c.541C>T p.L181F | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1166722525; called by muse, mutect2
- FAM184B | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1160276217, COSV99401210; called by muse, mutect2, varscan2
- FBXW11 | c.651+2T>A p.X217_splice | Splice Site (SNP) | VAF 7/10 reads (70%) | catalogued as COSV51606326; called by muse, mutect2, varscan2
- FLYWCH1 | c.1240G>A p.A414T (on ENST00000253928 / NM_001308068.2; = p.A413T on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as rs529892902, COSV54146544; called by muse, mutect2, varscan2
- GLRB | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.51); PolyPhen benign (0.197); catalogued as rs1355064370; called by muse, mutect2, varscan2
- GRID2IP | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745505031; called by muse, mutect2, varscan2
- IFIT5 | c.1276A>G p.K426E | Missense Mutation (SNP) | VAF 129/248 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs1166831709; called by muse, mutect2, varscan2
- IGLV5-45 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as rs773829774; called by muse, mutect2, varscan2
- KRTAP4-8 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs753185136; called by muse, mutect2, varscan2
- LRFN1 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV99953242; called by muse, mutect2, varscan2
- LRP3 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.489); catalogued as rs752590244; called by muse, mutect2, varscan2
- NCKIPSD | c.172-3dup | Splice Region (INS) | VAF 10/22 reads (45%) | catalogued as rs768132931; called by mutect2, varscan2
- NF1 | c.6643-2del p.X2215_splice (on ENST00000358273 / NM_001042492.3; = p.X2194_splice on NM_000267.3) | Splice Site (DEL) | VAF 7/60 reads (12%) | catalogued as CS1311543, COSV100646014; called by mutect2, pindel, varscan2
- OR7C2 | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 27/49 reads (55%) | catalogued as COSV50181190; called by muse, mutect2, varscan2
- PIK3CG | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63246545; called by muse, mutect2
- PRELID3B | c.90C>G p.N30K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV63504991; called by muse, mutect2
- PRR23B | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV61493538; called by muse, mutect2, varscan2
- PRRC1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as rs753950329; called by muse, mutect2, varscan2
- SLC22A2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1017655480; called by muse, mutect2, varscan2
- TAPBP | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747417254; called by muse, mutect2, varscan2
- TMEM143 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs968805183; called by muse, mutect2
- ULK2 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555564430; called by muse, mutect2, varscan2
- ADAMTS2 | c.1864T>C p.F622L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ALMS1 | c.12299-1G>C p.X4100_splice | Splice Site (SNP) | VAF 83/132 reads (63%) | called by muse, mutect2, varscan2
- AMZ1 | c.963G>A p.W321* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- BCL9 | c.3371C>A p.S1124Y | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- C14orf93 | c.1409A>C p.N470T | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCIN | c.1708C>A p.L570M | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FBLN1 | c.1574-2A>C p.X525_splice | Splice Site (SNP) | VAF 57/171 reads (33%) | called by muse, mutect2, varscan2
- HAO2 | c.59_72del p.S20Yfs*2 | Frame Shift Del (DEL) | VAF 98/265 reads (37%) | called by mutect2, pindel, varscan2
- KIF26A | c.3876G>T p.R1292S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PEDS1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RBM4B | c.101T>C p.I34T | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2
- RXFP1 | c.216T>A p.F72L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- RXFP2 | c.1638G>C p.W546C | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNN1A | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- SPATA6 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPTBN4 | c.680T>G p.V227G | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.199); called by muse, mutect2
- STRA8 | c.447-3C>T | Splice Region (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- SYN2 | c.1582C>G p.P528A | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENM4 | c.1255+1G>T p.X419_splice | Splice Site (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- TGS1 | c.1764_1765del p.D590Qfs*9 | Frame Shift Del (DEL) | VAF 31/118 reads (26%) | called by mutect2, pindel, varscan2
- TMEM176B | c.696del p.L232Ffs*9 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- TRHDE | c.1019C>A p.T340K | Missense Mutation (SNP) | VAF 64/135 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZDHHC11B | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ZNF225 | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ZNF277 | c.294-1G>A p.X98_splice | Splice Site (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- ANK1 | c.3297C>T p.A1099= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs1201691938; called by muse, varscan2
- CAMK2B | c.648C>T p.D216= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs773815200, COSV99323379; called by muse, mutect2, varscan2
- DNAH5 | c.10944T>C p.L3648= | Silent (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- ENPP6 | c.465A>T p.L155= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- FAAP100 | c.267G>A p.S89= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- FN1 | c.5754C>T p.S1918= | Silent (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- GALR1 | c.672T>A p.L224= | Silent (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- IGHV5-51 | c.66G>A p.Q22= | Silent (SNP) | VAF 98/192 reads (51%) | catalogued as rs567423875; called by muse, varscan2
- IGLL5 | c.114G>A p.L38= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as rs556230331, COSV73249618, COSV73250730; called by muse, varscan2
- IGLV3-1 | c.336C>T p.S112= | Silent (SNP) | VAF 46/49 reads (94%) | catalogued as rs73880716; called by muse, varscan2
- IGLV7-46 | c.228C>T p.H76= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs185250547; called by muse, mutect2, varscan2
- KCTD15 | c.687G>A p.S229= | Silent (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- LIM2 | c.504C>T p.R168= (on ENST00000596399 / NM_001161748.2; = p.R210= on NM_030657.4) | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- LTBP2 | c.1281C>T p.C427= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs375630948; called by muse, mutect2, varscan2
- NMUR1 | c.240G>A p.L80= | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.2220C>A p.A740= | Silent (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- TMEM132D | c.528C>A p.T176= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV101397450, COSV70611344; called by muse, varscan2
- TP53BP1 | c.2301A>G p.R767= | Silent (SNP) | VAF 55/129 reads (43%) | called by muse, mutect2, varscan2
- AC016705.2 | n.270G>T | RNA (SNP) | VAF 20/409 reads (5%) | catalogued as rs965442379; called by muse, mutect2
- AC100868.1 | c.*76C>T | 3'UTR (SNP) | VAF 49/101 reads (49%) | called by muse, mutect2, varscan2
- AC124067.4 | n.1635C>T | RNA (SNP) | VAF 24/62 reads (39%) | called by muse, varscan2
- AC136759.1 | n.972G>T | RNA (SNP) | VAF 62/137 reads (45%) | catalogued as rs747479276; called by muse, mutect2, varscan2
- ACOT11 | c.-10A>T | 5'UTR (SNP) | VAF 3/52 reads (6%) | called by muse, mutect2
- AL356414.1 | n.47G>T | RNA (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- AP3B2 | c.1971+160G>C | Intron (SNP) | VAF 32/68 reads (47%) | catalogued as rs1009956106; called by muse, mutect2, varscan2
- APTX | c.134-184T>A | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- ARHGAP32 | c.*3764A>T | 3'UTR (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021085 A>G | 5'Flank (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- BRAF | c.*225C>G | 3'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- C8orf34-AS1 | n.847C>A | RNA (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- C8orf82 | c.157-297G>A | Intron (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- CAPN3 | c.1782+259C>A | Intron (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- CCDC148 | c.*199A>T | 3'UTR (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- CCDC74B | c.250+13G>A | Intron (SNP) | VAF 8/36 reads (22%) | catalogued as rs747776073; called by muse, mutect2, varscan2
- COG8 | c.*273G>C | 3'UTR (SNP) | VAF 20/211 reads (9%) | called by muse, mutect2
- CYS1 | c.*322C>T | 3'UTR (SNP) | VAF 22/172 reads (13%) | called by muse, varscan2
- DDX19A | c.*230del | 3'UTR (DEL) | VAF 44/107 reads (41%) | catalogued as rs1187249545; called by mutect2, pindel, varscan2
- DNAL1 | c.*670A>G | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- DSEL | c.*1829G>C | 3'UTR (SNP) | VAF 21/28 reads (75%) | called by muse, mutect2, varscan2
- EGR3 | c.*1608C>T | 3'UTR (SNP) | VAF 29/55 reads (53%) | called by muse, mutect2, varscan2
- ENKUR | c.*328T>C | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- FAM102A | c.-72G>C | 5'UTR (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- FBN1 | c.*530G>T | 3'UTR (SNP) | VAF 19/72 reads (26%) | catalogued as rs959092536; called by muse, mutect2, varscan2
- FES | c.*52C>T | 3'UTR (SNP) | VAF 16/31 reads (52%) | called by muse, mutect2, varscan2
- FZD7 | c.*1256_*1290delinsGTCTTCAGCCTCATAATAAAGGAAAGTTAATTA | 3'UTR (DEL) | VAF 5/29 reads (17%) | called by pindel, varscan2*
- GLIS3 | c.*2025A>T | 3'UTR (SNP) | VAF 15/24 reads (63%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.*665T>C | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- HES2 | c.*737G>T | 3'UTR (SNP) | VAF 60/131 reads (46%) | called by muse, mutect2, varscan2
- HSPA1B | chr6:31834909 T>G | 3'Flank (SNP) | VAF 8/33 reads (24%) | catalogued as rs950520942; called by mutect2, varscan2
- IGLV1-41 | n.117G>A | RNA (SNP) | VAF 26/50 reads (52%) | called by muse, mutect2
- IGLV1-41 | n.119G>A | RNA (SNP) | VAF 28/52 reads (54%) | catalogued as rs1269161260; called by muse, mutect2
- IGLV1-41 | n.210G>A | RNA (SNP) | VAF 41/78 reads (53%) | catalogued as rs527833904; called by muse, varscan2
- IGLV1-41 | n.267A>G | RNA (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2
- IL4R | c.671-93G>A | Intron (SNP) | VAF 5/9 reads (56%) | catalogued as rs1330020488; called by muse, mutect2
- IYD | c.*3034A>C | 3'UTR (SNP) | VAF 6/126 reads (5%) | called by muse, mutect2
- KPNA5 | c.*45+2631C>G | Intron (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- LIN28B | c.*4038G>A | 3'UTR (SNP) | VAF 16/218 reads (7%) | called by muse, mutect2
- MEGF9 | c.*3201A>T | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.605T>C | RNA (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- NCK2 | c.*510G>T | 3'UTR (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
- NDUFAF4 | c.*206C>A | 3'UTR (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- NLGN1 | c.*3453A>G | 3'UTR (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- NOX4 | c.58-101A>T | Intron (SNP) | VAF 124/270 reads (46%) | catalogued as COSV54451737; called by muse, mutect2, varscan2
- PCSK5 | c.2626+5737G>A | Intron (SNP) | VAF 17/36 reads (47%) | catalogued as rs1185878130; called by muse, mutect2, varscan2
- PMP2 | c.*704C>T | 3'UTR (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- POR | c.-18C>T | 5'UTR (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- PPFIA4 | c.*2055C>T | 3'UTR (SNP) | VAF 18/92 reads (20%) | called by muse, mutect2, varscan2
- PROS1 | c.-8G>C | 5'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- PRRX1 | chr1:170663491 TAATTCTTAAT>AATTCTTAA | 5'Flank (DEL) | VAF 7/67 reads (10%) | called by pindel, varscan2*
- PSPH | c.*36G>A | 3'UTR (SNP) | VAF 34/76 reads (45%) | catalogued as rs762540857; called by muse, mutect2, varscan2
- RAB34 | c.*263C>A | 3'UTR (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- RIC3 | c.522-1412G>A | Intron (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- RNF215 | c.*561G>A | 3'UTR (SNP) | VAF 4/53 reads (8%) | called by muse, mutect2
- RNU1-5P | chr1:16871147 A>G | 5'Flank (SNP) | VAF 25/122 reads (20%) | called by muse, mutect2
- RPS6KA2 | c.*1025C>A | 3'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- RSPRY1 | c.*940C>T | 3'UTR (SNP) | VAF 17/48 reads (35%) | catalogued as rs1372666769; called by muse, mutect2, varscan2
- SCN3B | c.*2522C>G | 3'UTR (SNP) | VAF 37/39 reads (95%) | called by muse, mutect2, varscan2
- SCP2 | c.1548+1271T>C | Intron (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- SLC18A1 | c.*200C>T | 3'UTR (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- SLC23A2 | c.1102+37C>T | Intron (SNP) | VAF 17/38 reads (45%) | catalogued as rs754759159, COSV57776918; called by muse, mutect2, varscan2
- SLC9A3 | c.*1996C>T | 3'UTR (SNP) | VAF 38/82 reads (46%) | catalogued as rs929206424; called by muse, mutect2, varscan2
- SPDL1 | c.160-282A>G | Intron (SNP) | VAF 60/150 reads (40%) | called by muse, mutect2, varscan2
- SYNRG | c.*3622_*3623del | 3'UTR (DEL) | VAF 12/42 reads (29%) | called by pindel, varscan2
- TACC1 | c.*3150A>C | 3'UTR (SNP) | VAF 35/81 reads (43%) | called by muse, mutect2, varscan2
- TAF10 | c.232+34G>A | Intron (SNP) | VAF 20/52 reads (38%) | catalogued as rs1432635281; called by muse, mutect2, varscan2
- TMEM273 | c.294-76T>A | Intron (SNP) | VAF 110/284 reads (39%) | called by muse, mutect2, varscan2
- VEGFC | c.-130G>C | 5'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- ZBTB14 | c.*151G>A | 3'UTR (SNP) | VAF 39/110 reads (35%) | called by muse, mutect2, varscan2
- ZC3H3 | c.*394G>A | 3'UTR (SNP) | VAF 17/53 reads (32%) | catalogued as rs530505802; called by muse, mutect2, varscan2
- ZNF462 | c.6832+84C>A | Intron (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
